Somatic mutation profile of tumor specimen TCGA-2J-AABV-01A (aliquot TCGA-2J-AABV-01A-12D-A40W-08) from TCGA case TCGA-2J-AABV, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 74.1 years (27,082 days).
Specimen TCGA-2J-AABV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8622392-669d-4bb1-b2fc-982e7d832fb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABV-10A (Blood Derived Normal), aliquot TCGA-2J-AABV-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/466b0dce-e324-46cf-957a-3375a0fce311

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC2 | c.12823G>A p.D4275N | Missense Mutation (SNP) | VAF 36/1325 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55336297, COSV55347556; called by muse, mutect2
- PCDHA1 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 26/650 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV100974316; called by muse, mutect2
- RICTOR | c.2674G>A p.G892S | Missense Mutation (SNP) | VAF 17/659 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99704575; called by muse, mutect2
- TBX22 | c.805A>G p.K269E | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100960680; called by muse, mutect2
- SCN8A | c.2198G>A p.W733* | Nonsense Mutation (SNP) | VAF 37/842 reads (4%) | called by muse, mutect2
- ANKRD50 | c.600T>A p.I200= | Silent (SNP) | VAF 19/698 reads (3%) | catalogued as COSV101538909; called by muse, mutect2
- TYK2 | c.3243G>A p.A1081= | Silent (SNP) | VAF 20/508 reads (4%) | catalogued as COSV99314446; called by muse, mutect2
